Surgical pathology report (de-identified scan), TCGA case TCGA-AN-A0FT, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Cureline, specimen TCGA-AN-A0FT-01A (Primary Tumor).

TSS Patient ID:

Case #: DOB: Sex: **Female** Ethnicity (Race):

Cancer Sample

Diagnosis: **Breast Cancer** Histological description: **Infiltrative ductal carcinoma**

Date of Procurement: Anatomic Site: **Right breast** Tumor location: **Primary**

Tissue Specification: **Tumor** Specimen Matrix: **Tissue** Specimen Format: **OCT**

Container: **block** Type of Procurement: **surgery** Grade: **2**

T Stage: **2** N Stage: **1** M Stage: **0** Treatment: **none**

Treatment Details: **n/a**

Normal Sample

Anatomic Site: **Blood** Sample Type: **Normal** Type of Procurement: **blood draw**

Matrix: **Blood** Specimen Format: **frozen** Container: **tube**

Date of Procurement:

*ICD-0-3
carcinoma, infiltrating duct, NOS 8500/3
Site: breast, NOS C50.9 lw 10/21/11*

lw 10/21/11		

Source: NCI Genomic Data Commons file 8e57c7c9-ba64-4508-bb4f-201fcb5ed6dd (TCGA-AN-A0FT.338D5387-0CFB-4D91-944F-1F054C21C769.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).